TCGA case TCGA-22-5471 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Mayo Clinic - Rochester. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bece6b8e-5d6c-4dd6-85a3-9b3a9c670aa7

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: United States; Age at index: 75 years; Vital status: Alive.

Diagnoses (3)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 76.0 years (27,749 days); Year of diagnosis: 2005; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R2; Days to last follow up: 1,845 days (5.1 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment end: 174 days; Course number: 1; Treatment anatomic sites: Primary Tumor Field.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.
2. Melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Head, face or neck, NOS; Laterality: Right; Classification of tumor: Prior primary.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 76.6 years (27,978 days); Days to diagnosis: 229 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 229 days; Treatment anatomic sites: Locoregional Site.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (3 entries)
- Day 229 (post initial treatment): Progression or recurrence: Yes.
- ECOG performance status: 1; Timepoint: Prior to Adjuvant Therapy.
- Follow-up contacts recording only the day: day 964, day 965, day 1,845.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 50; Tobacco smoking quit year: 2005.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-22-5471-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.9; Intermediate dimension: 0.5; Shortest dimension: 0.4.
  Slide TCGA-22-5471-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 20; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 5.
- Sample TCGA-22-5471-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-22-5471-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.5; Intermediate dimension: 0.8; Shortest dimension: 0.4.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Performance status timing: Pre-Adjuvant Therapy; Tobacco smoking history indicator: 4; Anatomic organ subdivision: L-Lower; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No.
- Follow-up form 1: Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: Yes; New tumor event surgery: Yes; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 2: Lost to follow-up: Yes; Treatment outcome first course: Complete Remission/Response.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Neck; Other malignancy histological type: Melanoma.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Prior malignancy melanoma of the neck. No systemic chemotherapy or radiation.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,845 days; disease-specific survival: no event (censored), 1,845 days; disease-free interval: event (new tumor event after initially disease-free), 229 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 229 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-22-5471-01A-01D-1631-01): tumor purity 0.44, ploidy 3.26, whole-genome doublings 1.
